Somatic mutation profile of tumor specimen TCGA-18-3421-01A (aliquot TCGA-18-3421-01A-01D-0983-08) from TCGA case TCGA-18-3421, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.6 years (23,972 days).
Specimen TCGA-18-3421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcdc27e6-75a3-4fdb-8af1-80008baadc17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3421-11A (Solid Tissue Normal), aliquot TCGA-18-3421-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a58006c-fbe7-4a0c-a089-549b5d7a800b

The open-access MAF lists 335 somatic variants for this specimen: 255 protein-altering or splice-affecting, 73 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 73, Nonsense Mutation 14, Frame Shift Del 11, Splice Site 8, RNA 3, In Frame Del 3, 5'Flank 2, Splice Region 1, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 47/66 reads (71%) | catalogued as rs886037972, CM167108, COSV58785930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 14/33 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1131691021, COSV52683521, COSV52729554, COSV52811339, COSV52993405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASS | c.1974G>C p.L658F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62789285; called by muse, mutect2, varscan2
- ABCA9 | c.4815T>A p.D1605E | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV60621823; called by muse, mutect2, varscan2
- ABCC8 | c.4546-1G>T p.X1516_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | catalogued as CS131685, COSV56847377; called by muse, mutect2, varscan2
- ABCC8 | c.4546-2A>T p.X1516_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | catalogued as COSV56847384; called by muse, mutect2, varscan2
- AC011448.1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs368324977; called by mutect2, varscan2
- ADGRB3 | c.3595G>C p.V1199L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV53237726, COSV53246916; called by muse, mutect2, varscan2
- ADGRE3 | c.1475C>A p.T492N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53728831; called by muse, mutect2, varscan2
- ADGRF2 | c.889A>G p.I297V (on ENST00000296862 / NM_001368115.2; = p.I229V on NM_153839.7) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs767511412, COSV57287057; called by muse, mutect2, varscan2
- ADGRL3 | c.791C>A p.P264Q (on ENST00000506720 / NM_001322402.2; = p.P196Q on NM_015236.6) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.264); catalogued as COSV72266815; called by muse, mutect2, varscan2
- ADNP | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.354); catalogued as COSV62424708; called by muse, mutect2, varscan2
- ADPRH | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63694580; called by muse, mutect2, varscan2
- AFAP1L2 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58412967; called by muse, mutect2, varscan2
- AFF2 | c.1662G>C p.E554D | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as COSV53980460, COSV53988491; called by muse, mutect2, varscan2
- AGMO | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV61107792; called by muse, mutect2, varscan2
- AHCTF1 | c.2932C>T p.Q978* (on ENST00000366508; = p.Q952* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs868440709, COSV58246927; called by mutect2, varscan2
- AKAP17A | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58308707; called by muse, mutect2, varscan2
- AKAP3 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57414735; called by muse, mutect2, varscan2
- AKAP6 | c.4659G>C p.M1553I | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55207384; called by muse, mutect2, varscan2
- ANKRD34A | c.913G>C p.V305L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV60160385; called by muse, mutect2, varscan2
- ANKRD55 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61944853; called by muse, mutect2, varscan2
- APOB | c.6271G>T p.V2091L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs757141693, COSV99263622; called by muse, mutect2, varscan2
- ARNT2 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57582551; called by muse, mutect2, varscan2
- ATAD5 | c.5174C>T p.S1725L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58971948, COSV58972611; called by muse, mutect2, varscan2
- ATP10B | c.621G>C p.L207F | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58778043; called by muse, mutect2, varscan2
- B3GNT8 | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54195852; called by muse, mutect2, varscan2
- BOLA1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64966676; called by muse, mutect2, varscan2
- BPI | c.641C>T p.S214F (on ENST00000262865; = p.S210F on NM_001725.3) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53404316; called by muse, mutect2, varscan2
- C1QTNF9 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656575; called by muse, mutect2, varscan2
- C2CD3 | c.1255G>T p.G419C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58090778; called by muse, mutect2, varscan2
- C6orf15 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV52537487, COSV52538206; called by mutect2, varscan2
- C8orf76 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV52690102; called by muse, mutect2, varscan2
- CACNG6 | c.608T>C p.V203A (on ENST00000252729 / NM_145814.1; = p.V132A on NM_031897.2) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV53165983; called by muse, mutect2, varscan2
- CARD11 | c.1730A>T p.Y577F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62754400; called by muse, mutect2
- CCDC102A | c.871A>C p.K291Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50775901; called by muse, mutect2, varscan2
- CD44 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53528447; called by muse, mutect2
- CDH10 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as COSV100049556, COSV52573536; called by muse, mutect2, varscan2
- CDHR3 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 93/151 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58414889; called by muse, mutect2, varscan2
- CELSR1 | c.8596C>T p.Q2866* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53085280; called by muse, mutect2, varscan2
- CELSR1 | c.4445A>G p.N1482S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV53085293; called by muse, mutect2, varscan2
- CFAP58 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as COSV63833036; called by muse, mutect2, varscan2
- CFAP61 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1045451131, COSV55622098; called by mutect2, varscan2
- CLEC11A | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs973363881, COSV51573623; called by muse, mutect2, varscan2
- CNNM2 | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV63995659; called by muse, mutect2, varscan2
- COL25A1 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67647613; called by muse, mutect2, varscan2
- COL28A1 | c.3372A>T p.Q1124H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV68081021; called by mutect2, varscan2
- COL4A2 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64625001; called by muse, mutect2
- COL9A2 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV65607218; called by muse, varscan2
- CRISP1 | c.623-1G>C p.X208_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100236603; called by muse, mutect2, varscan2
- CSF2RA | c.44A>C p.H15P | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV62623831; called by muse, mutect2, varscan2
- CST11 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65440538; called by muse, mutect2, varscan2
- CYP1A1 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV65696757; called by muse, mutect2, varscan2
- CYP46A1 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV55893430; called by muse, mutect2, varscan2
- DGKK | c.3073A>T p.R1025* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV65706676; called by muse, mutect2, varscan2
- DNAH8 | c.7630C>A p.Q2544K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59431266; called by muse, mutect2, varscan2
- DNAH8 | c.7631A>G p.Q2544R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59431279; called by muse, mutect2, varscan2
- DOCK11 | c.3202G>C p.E1068Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV52235085; called by muse, mutect2, varscan2
- DYRK1A | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV58292792, COSV58297554; called by muse, mutect2, varscan2
- EIF2B3 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.212); catalogued as COSV64516973; called by muse, mutect2, varscan2
- EPHA3 | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60697556; called by muse, varscan2
- ERICH1 | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as COSV50637399; called by mutect2, varscan2
- ETFDH | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs140184655; called by muse, mutect2, varscan2
- F5 | c.1416C>G p.I472M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV63121652, COSV63129185; called by muse, mutect2, varscan2
- FAM135B | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 104/178 reads (58%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1488957859, COSV52711475; called by muse, mutect2, varscan2
- FAM135B | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as COSV50522048, COSV50523292; called by muse, mutect2, varscan2
- FAM170A | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 96/170 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58924401; called by muse, mutect2, varscan2
- FAM181A | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751346175, COSV50887889; called by mutect2, varscan2
- FAM71F2 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV66351921; called by muse, mutect2, varscan2
- FAT3 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs778188769, COSV53086371; called by muse, mutect2, varscan2
- FGA | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV57393907, COSV57394365; called by muse, mutect2, varscan2
- FLG | c.5945C>A p.T1982K | Missense Mutation (SNP) | VAF 234/474 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV64238170; called by muse, varscan2
- FLG | c.2105C>G p.S702* | Nonsense Mutation (SNP) | VAF 205/489 reads (42%) | catalogued as COSV64238176; called by muse, mutect2, varscan2
- FLNC | c.6221T>A p.L2074* | Nonsense Mutation (SNP) | VAF 28/41 reads (68%) | catalogued as COSV57952126; called by muse, mutect2, varscan2
- FYB1 | c.910T>A p.L304M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV60942360; called by muse, mutect2, varscan2
- GABRB3 | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV54653901; called by muse, mutect2, varscan2
- GALNTL6 | c.386+1G>A p.X129_splice | Splice Site (SNP) | VAF 17/86 reads (20%) | catalogued as COSV71826895; called by muse, mutect2, varscan2
- GCK | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61752823, COSV61755017; called by muse, mutect2, varscan2
- GCNT3 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV68532013; called by muse, mutect2, varscan2
- GFPT2 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV53806905; called by muse, mutect2, varscan2
- GLDN | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59089174; called by muse, mutect2, varscan2
- GOLM2 | c.1165T>A p.Y389N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55462078; called by muse, mutect2, varscan2
- GTPBP4 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62550325; called by muse, mutect2, varscan2
- ICAM5 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV53423947; called by muse, mutect2
- IFIT3 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV51078228; called by muse, mutect2, varscan2
- IFNL3 | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV69829840; called by muse, mutect2, varscan2
- IFT88 | c.661A>G p.M221V (on ENST00000319980 / NM_001318493.2; = p.M212V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60671966; called by muse, mutect2, varscan2
- IGF2BP1 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 70/136 reads (51%) | catalogued as COSV51729816, COSV51732290; called by muse, mutect2, varscan2
- IGKV1-5 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs753377420; called by muse, mutect2, varscan2
- IMPDH2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs779639948, COSV58707430; called by muse, mutect2, varscan2
- IQCF2 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs905610389, COSV60761222; called by muse, mutect2, varscan2
- IRAG1 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.205); catalogued as COSV70210289; called by muse, mutect2, varscan2
- ITLN2 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV63537513; called by muse, mutect2, varscan2
- KHDRBS1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV56981345; called by muse, mutect2, varscan2
- KIAA0232 | c.4136G>T p.G1379V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV56923816; called by mutect2, varscan2
- KIAA1549 | c.4837G>T p.D1613Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54307865, COSV54315621; called by muse, mutect2, varscan2
- KIAA1549L | c.293G>T p.G98V (on ENST00000321505; = p.G395V on NM_012194.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV55770706; called by muse, mutect2, varscan2
- KIF4B | c.2661C>A p.S887R | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV70528318; called by muse, mutect2, varscan2
- KIRREL2 | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52874804; called by muse, mutect2, varscan2
- KRTAP10-3 | c.235T>G p.C79G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100551932; called by mutect2, varscan2
- LCN1 | c.506-2A>G p.X169_splice | Splice Site (SNP) | VAF 27/55 reads (49%) | catalogued as COSV55017545; called by muse, mutect2, varscan2
- LCT | c.1225A>C p.S409R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51545401; called by muse, mutect2, varscan2
- LEF1 | c.208C>G p.H70D | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV54464990; called by muse, mutect2, varscan2
- LHX8 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); catalogued as COSV53954962; called by muse, mutect2, varscan2
- LRP1B | c.12812C>A p.P4271H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67196445, COSV67255763; called by mutect2, varscan2
- LRP2 | c.9440A>G p.K3147R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV55544767; called by muse, mutect2, varscan2
- LRRC7 | c.2439C>A p.D813E (on ENST00000651989 / NM_001370785.2; = p.D780E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50420317; called by muse, mutect2, varscan2
- MACC1 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV60541327; called by muse, mutect2, varscan2
- MACF1 | c.17065G>A p.E5689K (on ENST00000372915; = p.E3731K on NM_012090.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV57110549; called by muse, mutect2, varscan2
- MAGEL2 | c.3029C>A p.S1010Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV58566252; called by mutect2, varscan2
- MAP2 | c.1601A>C p.Q534P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV52284228; called by muse, mutect2, varscan2
- MAP4K4 | c.3055G>A p.D1019N (on ENST00000347699 / NM_001242559.2; = p.D937N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV56326765; called by muse, mutect2, varscan2
- MAPK9 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs780562313, COSV58119465; called by muse, mutect2, varscan2
- MCPH1 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs753406650, COSV60911119; called by muse, mutect2, varscan2
- MS4A6E | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as COSV55726142, COSV55726338; called by muse, mutect2
- MTOR | c.2204T>G p.I735S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV63869142, COSV63869829; called by muse, mutect2, varscan2
- MUC16 | c.33641G>C p.S11214T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.685); catalogued as COSV67452185; called by muse, mutect2, varscan2
- MUC16 | c.11112T>A p.D3704E | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV67452192; called by muse, mutect2, varscan2
- MYO18B | c.4018A>G p.I1340V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as rs765591664, COSV59128244; called by muse, mutect2, varscan2
- MYO5B | c.3277-1G>T p.X1093_splice | Splice Site (SNP) | VAF 66/100 reads (66%) | catalogued as COSV53213299; called by muse, varscan2
- NBEAL2 | c.354G>T p.L118= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as COSV52755066, COSV52758895; called by muse, mutect2, varscan2
- NKG7 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52467174; called by muse, mutect2, varscan2
- NOP2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1289639693, COSV58896233; called by muse, mutect2, varscan2
- NOX3 | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV50149242; called by muse, mutect2, varscan2
- NPVF | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV56060307; called by muse, mutect2, varscan2
- NRK | c.794C>G p.A265G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54591714; called by muse, mutect2
- NRXN3 | c.1765C>A p.R589S (on ENST00000335750 / NM_001330195.2; = p.R216S on NM_004796.6) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV100200838, COSV59816102; called by muse, mutect2, varscan2
- NXPE3 | c.1680G>T p.*560Yext*17 | Nonstop Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV56289056; called by muse, mutect2, varscan2
- OAS1 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1021340095, COSV52534554, COSV52536141; called by muse, mutect2, varscan2
- OASL | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV57477607; called by muse, mutect2, varscan2
- OR10J5 | c.810C>A p.D270E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs755296633, COSV58385132; called by muse, mutect2, varscan2
- OR1L3 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs372085770; called by muse, mutect2, varscan2
- OR4B1 | c.78T>A p.F26L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58882228, COSV58884249; called by muse, mutect2, varscan2
- OR4C13 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs190982976, COSV73648668; called by muse, mutect2, varscan2
- OR4D11 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57584973; called by muse, mutect2, varscan2
- OR4F15 | c.137T>A p.V46E | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV59968488; called by muse, mutect2, varscan2
- OR4N2 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV60050408; called by muse, mutect2, varscan2
- OR5L2 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as rs926362588, COSV65723568; called by muse, mutect2, varscan2
- OR5P2 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs1476294027, COSV61490092; called by muse, mutect2, varscan2
- OR6N2 | c.149del p.R50Hfs*85 | Frame Shift Del (DEL) | VAF 62/200 reads (31%) | catalogued as COSV59410931; called by mutect2, pindel, varscan2
- OR8I2 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1279557654, COSV56166954; called by muse, mutect2, varscan2
- OSCP1 | c.866A>T p.N289I (on ENST00000356637 / NM_001330493.1; = p.N279I on NM_145047.5) | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV52485168; called by muse, mutect2, varscan2
- PADI3 | c.473A>C p.D158A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV64934124; called by muse, mutect2, varscan2
- PARP11 | c.950A>T p.N317I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV57393949; called by muse, mutect2
- PARP8 | c.1045A>T p.R349W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55857028; called by muse, mutect2, varscan2
- PCDH1 | c.2798T>A p.L933Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.901); catalogued as COSV54611900; called by muse, mutect2, varscan2
- PCDH11X | c.3062C>A p.T1021N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.328); catalogued as COSV53449986; called by muse, mutect2, varscan2
- PCDHGA7 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV53912777, COSV99545727; called by muse, mutect2, varscan2
- PCLAF | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55539912, COSV55540442; called by muse, mutect2, varscan2
- PHACTR3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs145693547; called by muse, mutect2, varscan2
- PHLDB2 | c.509G>C p.R170P | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as COSV67307376, COSV67308993; called by muse, varscan2
- PHLPP1 | c.3316G>C p.E1106Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as COSV53024251, COSV99407524; called by muse, mutect2, varscan2
- PIGZ | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.555); catalogued as COSV53013240; called by muse, mutect2, varscan2
- PKD1L1 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV56960258, COSV56978720; called by muse, mutect2, varscan2
- PKHD1 | c.9671C>A p.A3224D | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61864897; called by muse, mutect2, varscan2
- PLA2G6 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs375740918; called by muse, mutect2, varscan2
- PLCXD2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV67338789; called by muse, mutect2, varscan2
- PLEK2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs749357488, COSV53604418; called by muse, mutect2, varscan2
- POLE | c.6105G>T p.Q2035H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as COSV57675910; called by mutect2, varscan2
- PRC1 | c.201A>C p.K67N | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV62694437; called by muse, mutect2
- PRKDC | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1302651751, COSV58046345; called by muse, mutect2, varscan2
- PRPH | c.1160T>C p.M387T | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV57678101; called by muse, mutect2, varscan2
- PSEN2 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60915188; called by muse, mutect2, varscan2
- PTCHD4 | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59779785; called by muse, mutect2, varscan2
- PTEN | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 44/69 reads (64%) | catalogued as rs1554825200, CM1310837, COSV64291436, COSV64298657, COSV64300002; called by muse, mutect2, varscan2
- PTPRH | c.1952A>T p.D651V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV54743459; called by muse, mutect2, varscan2
- PUM1 | c.2902C>G p.Q968E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV57082621; called by muse, mutect2, varscan2
- PXDNL | c.4115T>A p.I1372N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV62481736; called by muse, mutect2, varscan2
- RDH11 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV67282505; called by muse, mutect2, varscan2
- RDH16 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62457963; called by muse, mutect2, varscan2
- REEP2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1226384099, COSV54734669; called by muse, mutect2, varscan2
- RESF1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV57020270; called by muse, mutect2, varscan2
- RPE65 | c.1010T>G p.V337G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52013943; called by muse, mutect2, varscan2
- RSPH6A | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV55570537; called by muse, mutect2, varscan2
- RYR1 | c.1987T>C p.F663L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62091743; called by muse, mutect2, varscan2
- RYR1 | c.7943A>G p.Y2648C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62091748; called by muse, mutect2, varscan2
- SAMD3 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.362); catalogued as COSV60774487; called by muse, mutect2, varscan2
- SEZ6L2 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV58097815; called by muse, mutect2, varscan2
- SFSWAP | c.2162G>T p.C721F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV55520368; called by muse, mutect2, varscan2
- SGIP1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV52764383; called by muse, mutect2, varscan2
- SIM1 | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV53489755; called by muse, mutect2, varscan2
- SLAIN2 | c.1510C>G p.P504A | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.115); catalogued as COSV51904922; called by muse, mutect2, varscan2
- SLC22A2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65265552; called by muse, varscan2
- SLC25A31 | c.540T>A p.D180E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV55418323; called by muse, mutect2, varscan2
- SLC44A2 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59835519; called by muse, mutect2, varscan2
- SLC6A7 | c.1290C>G p.I430M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV57937206; called by muse, mutect2, varscan2
- SLC7A1 | c.1116T>G p.F372L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV66329897; called by muse, mutect2, varscan2
- SOS1 | c.2116A>T p.R706* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV67674214; called by mutect2, varscan2
- SPATA31D1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV100782474; called by muse, mutect2, varscan2
- SPTLC3 | c.548C>A p.T183K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV65464206; called by muse, mutect2, varscan2
- ST3GAL4 | c.767A>C p.K256T (on ENST00000392669 / NM_001254758.1; = p.K252T on NM_006278.3) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV57106317; called by muse, mutect2, varscan2
- STAG3 | c.3568T>G p.S1190A | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV57928281; called by muse, varscan2
- SV2C | c.1546G>C p.V516L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59215847; called by muse, mutect2, varscan2
- SVIL | c.3085T>G p.L1029V (on ENST00000355867 / NM_021738.3; = p.L603V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV63441017; called by muse, mutect2, varscan2
- SYNCRIP | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.964); catalogued as COSV62286853, COSV62287000; called by mutect2, varscan2
- SYNDIG1 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV65232882; called by muse, mutect2, varscan2
- SYNJ2 | c.563T>G p.V188G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.078); catalogued as COSV62895915; called by muse, mutect2, varscan2
- TANGO6 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746976251, COSV55761899; called by muse, mutect2, varscan2
- TENM4 | c.4304A>G p.N1435S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV53614689; called by muse, mutect2, varscan2
- TIGD3 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745340625, COSV52888123; called by mutect2, varscan2
- TIMM21 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV50053404; called by muse, mutect2, varscan2
- TLR4 | c.659C>A p.P220Q (on ENST00000355622 / NM_138554.5; = p.P180Q on NM_003266.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs760785276, COSV62922649; called by muse, mutect2, varscan2
- TMEM174 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57113288, COSV99703746; called by muse, mutect2, varscan2
- TNR | c.3442T>G p.L1148V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.892); catalogued as COSV54874995; called by muse, mutect2, varscan2
- TRIM47 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs778714456, COSV54667860; called by mutect2, varscan2
- TRPM6 | c.4004G>T p.R1335M | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.19); catalogued as COSV62504578; called by muse, mutect2, varscan2
- TRPM8 | c.1413del p.K472Sfs*11 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as COSV100224489; called by mutect2, pindel, varscan2
- TSG101 | c.194-2A>C p.X65_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV52648890; called by muse, mutect2, varscan2
- TST | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV50764905; called by muse, mutect2, varscan2
- TTC14 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV56009917; called by mutect2, varscan2
- TTI1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1302209106, COSV65060804; called by muse, mutect2, varscan2
- TTN | c.92636G>C p.W30879S (on ENST00000591111; = p.W23455S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59931491; called by muse, mutect2, varscan2
- TTN | c.32783C>T p.P10928L (on ENST00000591111; = p.P10001L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | PolyPhen possibly damaging (0.714); catalogued as COSV59931552; called by muse, mutect2, varscan2
- TTN | c.10231G>A p.E3411K (on ENST00000591111; = p.E3365K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | PolyPhen probably damaging (0.994); catalogued as COSV59931567; called by muse, mutect2, varscan2
- TUSC3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs367660078, COSV65878877; called by mutect2, varscan2
- UBASH3A | c.1909G>C p.V637L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs747608906, COSV52311066; called by muse, mutect2, varscan2
- UQCRFS1 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59184444; called by muse, mutect2, varscan2
- VAMP7 | c.434-1G>T p.X145_splice | Splice Site (SNP) | VAF 13/61 reads (21%) | catalogued as COSV52901349, COSV52901776; called by muse, mutect2
- WDR7 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.444); catalogued as COSV54349566; called by muse, mutect2, varscan2
- XPNPEP3 | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV63210059; called by muse, mutect2, varscan2
- YY1AP1 | c.2218G>A p.E740K (on ENST00000295566 / NM_139118.2; = p.E683K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.828); catalogued as COSV55119574; called by muse, mutect2, varscan2
- ZBTB1 | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as COSV62437495; called by muse, mutect2, varscan2
- ZBTB2 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.257); catalogued as COSV57311902; called by muse, mutect2, varscan2
- ZBTB21 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.634); catalogued as COSV60403168; called by muse, mutect2, varscan2
- ZC3H11A | c.998A>T p.E333V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59744904; called by mutect2, varscan2
- ZCCHC12 | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as COSV59571117; called by muse, mutect2, varscan2
- ZEB2 | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57952926; called by muse, mutect2, varscan2
- ZFC3H1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66430863; called by muse, mutect2, varscan2
- ZFHX4 | c.8552C>G p.P2851R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs769744583, COSV50593001; called by muse, mutect2, varscan2
- ZHX2 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV58711058; called by muse, varscan2
- ZMAT2 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51226851; called by muse, mutect2, varscan2
- ZNF326 | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61034643; called by muse, mutect2, varscan2
- ZNF395 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392975448, COSV60427992; called by muse, mutect2, varscan2
- ZNF586 | c.1056A>C p.K352N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66972175; called by muse, mutect2, varscan2
- ZNF697 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70284035; called by mutect2, varscan2
- ZNF750 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV53958905; called by muse, mutect2, varscan2
- ZNF774 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs141917260; called by muse, mutect2, varscan2
- ZP4 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as COSV63911335; called by muse, mutect2, varscan2
- ZSWIM2 | c.186C>G p.H62Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54574250, COSV54576085; called by muse, mutect2, varscan2
- AMBRA1 | c.3045_3061del p.W1016Afs*8 (on ENST00000458649 / NM_001367468.1; = p.W926Afs*8 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel
- BAZ2A | c.4489_4516del p.F1497Pfs*10 | Frame Shift Del (DEL) | VAF 43/167 reads (26%) | called by mutect2, pindel
- GLYATL1 | c.244_256del p.P82Kfs*4 (on ENST00000317391 / NM_001354699.1; = p.P113Kfs*4 on NM_080661.4) | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- IGHV4-59 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ITIH3 | c.629del p.G210Efs*21 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- MROH2B | c.249dup p.A84Cfs*4 | Frame Shift Ins (INS) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- NPY2R | c.465_484del p.H155Qfs*32 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- NR3C2 | c.2092C>A p.P698T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by mutect2, varscan2
- PAG1 | c.146_161del p.H49Rfs*3 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- PRR3 | c.40_45del p.T14_Q15del | In Frame Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- RESF1 | c.3863_3874del p.P1288_N1291del | In Frame Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- TAS2R7 | c.688del p.H230Mfs*2 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- TEX14 | c.1720del p.V574Ffs*10 (on ENST00000240361 / NM_001201457.2; = p.V568Ffs*10 on NM_031272.5) | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- TPTE | c.1624A>T p.T542S (on ENST00000618007 / NM_199261.4; = p.T524S on NM_199259.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.01); called by muse, varscan2
- TTN | c.11346del p.A3783Pfs*4 (on ENST00000591111; = p.A3737Pfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by pindel, varscan2
- ZNF423 | c.1436_1459del p.V479_S486del (on ENST00000563137 / NM_001379286.1; = p.V471_S478del on NM_015069.4) | In Frame Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel
- AGRN | c.2172C>T p.T724= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65068200; called by muse, mutect2, varscan2
- AMPH | c.1836A>T p.A612= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV57736031; called by muse, mutect2, varscan2
- ANKEF1 | c.2328C>G p.T776= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV65692045; called by muse, mutect2, varscan2
- AOC1 | c.2007G>A p.V669= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV62867307; called by mutect2, varscan2
- APPBP2 | c.1026C>T p.V342= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV50026095; called by muse, mutect2, varscan2
- ASCC2 | c.1800G>A p.Q600= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV57072482; called by muse, mutect2
- BAZ1A | c.3252C>G p.L1084= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as COSV62409365, COSV62412293; called by muse, mutect2, varscan2
- CARD18 | c.51G>T p.V17= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV73233153; called by muse, mutect2, varscan2
- CASZ1 | c.891C>T p.H297= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV59733030; called by muse, mutect2, varscan2
- CCDC151 | c.1131G>T p.R377= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV62697384; called by mutect2, varscan2
- CCR6 | c.780G>T p.V260= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV59474217; called by muse, mutect2, varscan2
- CHIT1 | c.570T>C p.Y190= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as rs555993709, COSV55145595; called by muse, mutect2, varscan2
- COL11A1 | c.1761A>G p.G587= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV62175648; called by muse, mutect2, varscan2
- DBT | c.564G>A p.L188= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV64495037; called by muse, mutect2, varscan2
- DENND2B | c.1735C>T p.L579= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV58201995; called by muse, mutect2, varscan2
- DOCK11 | c.5544A>G p.T1848= | Silent (SNP) | VAF 69/105 reads (66%) | catalogued as COSV52235096; called by muse, mutect2, varscan2
- FAM47A | c.1578G>C p.R526= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV60494873; called by muse, varscan2
- FAM47A | c.1320C>T p.D440= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs775650386, COSV60494880, COSV60499976; called by muse, mutect2, varscan2
- FAM71D | c.24T>C p.T8= | Silent (SNP) | VAF 103/200 reads (52%) | catalogued as COSV61294823; called by muse, mutect2, varscan2
- FBXO16 | c.303T>C p.F101= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV60774783; called by muse, mutect2
- GCFC2 | c.732T>C p.D244= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV58080044; called by muse, mutect2, varscan2
- GLB1 | c.450C>T p.S150= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs140353187; called by muse, mutect2, varscan2
- GPR39 | c.876G>A p.L292= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV61415928; called by muse, varscan2
- GRXCR1 | c.75T>C p.S25= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs876657475, COSV67670634; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSPT1 | c.858A>G p.P286= (on ENST00000420576 / NM_001130007.2; = p.P424= on NM_002094.4) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs773228071, COSV70452494; called by muse, mutect2, varscan2
- GSTM5 | c.141G>T p.L47= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs754726820, COSV56656796; called by muse, mutect2, varscan2
- H4C5 | c.213G>A p.V71= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs779424083, COSV63486292; called by mutect2, varscan2
- HCN1 | c.2460G>C p.T820= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100299478, COSV57498006; called by muse, mutect2, varscan2
- INPP5E | c.642G>T p.S214= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV51523139; called by muse, mutect2, varscan2
- IRGC | c.1251G>C p.V417= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV54983226; called by muse, mutect2, varscan2
- KANK4 | c.1614C>A p.T538= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV62985747; called by muse, mutect2, varscan2
- KIF1B | c.1002G>T p.A334= (on ENST00000377086 / NM_001365952.1; = p.A328= on NM_015074.3) | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV55804834, COSV99822264; called by muse, mutect2, varscan2
- KLHL32 | c.456C>T p.D152= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1326091926, COSV65110839; called by muse, mutect2, varscan2
- KMT2E | c.1902A>G p.E634= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV57570639; called by muse, mutect2, varscan2
- LHCGR | c.1822C>T p.L608= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV54293906; called by muse, mutect2, varscan2
- LILRB4 | c.1239C>T p.Y413= (on ENST00000391733 / NM_001278428.3; = p.Y412= on NM_001278426.3) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs191773308; called by muse, varscan2
- LRP5 | c.3057C>G p.G1019= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV53712511, COSV53724005; called by muse, mutect2, varscan2
- LRRC20 | c.495G>A p.P165= (on ENST00000355790 / NM_207119.3; = p.P109= on NM_018205.4) | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as rs149319681; called by mutect2, varscan2
- MACC1 | c.1224T>C p.G408= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV60541319; called by muse, mutect2, varscan2
- MAPK7 | c.1341C>T p.D447= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1419932395, COSV55189669; called by muse, mutect2, varscan2
- MGAT3 | c.1314C>T p.G438= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1481248800, COSV57864444; called by muse, mutect2, varscan2
- MKNK2 | c.444C>T p.F148= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV51730989; called by muse, mutect2, varscan2
- MTA2 | c.1746G>C p.G582= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV53469121; called by muse, mutect2
- NFE2L1 | c.1194C>T p.P398= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV62582883; called by muse, mutect2, varscan2
- NUTM2G | c.1230G>A p.V410= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV63617005; called by muse, mutect2, varscan2
- OR4C6 | c.795A>T p.I265= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV58602856; called by muse, mutect2, varscan2
- OR6F1 | c.375C>T p.A125= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57467151; called by muse, mutect2, varscan2
- OR9G4 | c.447C>T p.Y149= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV57248012; called by muse, mutect2, varscan2
- OTULIN | c.684C>T p.L228= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs767120686, COSV52505134; called by mutect2, varscan2
- P4HTM | c.1506C>G p.L502= (on ENST00000383729 / NM_177939.3; = p.L563= on NM_177938.2) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs527458356, COSV59086210; called by muse, mutect2, varscan2
- PCDH11X | c.3063C>A p.T1021= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV53449998; called by muse, mutect2, varscan2
- PCDHB7 | c.1732C>A p.R578= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV50756530, COSV50784392; called by muse, varscan2
- PCDHGB5 | c.1845G>T p.L615= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV53912784; called by muse, mutect2, varscan2
- PRPF19 | c.1248C>G p.V416= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57127210; called by muse, mutect2, varscan2
- PRSS55 | c.690C>G p.T230= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100153722, COSV60807927; called by muse, mutect2, varscan2
- RAD21 | c.681A>G p.G227= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV52057140; called by muse, mutect2, varscan2
- RALGAPB | c.1338C>G p.L446= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs148846201, COSV53435481; called by muse, mutect2, varscan2
- RBP2 | c.360G>T p.L120= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV51673110; called by muse, mutect2, varscan2
- SACS | c.8916A>T p.P2972= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV66534266, COSV66536068; called by muse, mutect2, varscan2
- SCN1A | c.2523G>T p.T841= (on ENST00000303395 / NM_001202435.3; = p.T830= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV57663339, COSV57689265; called by muse, mutect2, varscan2
- SELENOV | c.753C>G p.P251= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV59063451; called by muse, mutect2
- SYT9 | c.258C>T p.G86= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs562479190, COSV59615538; called by muse, mutect2, varscan2
- TAS2R20 | c.586C>T p.L196= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs770627316, COSV67853383, COSV67861648; called by muse, mutect2, varscan2
- TMEM101 | c.651C>G p.L217= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV52812955; called by muse, mutect2, varscan2
- TMEM108 | c.345A>G p.T115= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV58866042; called by muse, mutect2, varscan2
- TMEM19 | c.792T>C p.A264= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV56999007; called by muse, mutect2, varscan2
- TMEM201 | c.939G>C p.L313= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV61051048; called by muse, mutect2, varscan2
- USP48 | c.2784A>G p.Q928= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV57607921; called by muse, mutect2, varscan2
- VPS54 | c.1353C>T p.L451= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs373361920, COSV55438450; called by mutect2, varscan2
- WDR61 | c.489A>T p.L163= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- ZNF16 | c.1188G>A p.Q396= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV52762959; called by muse, mutect2, varscan2
- ZNF615 | c.837G>A p.Q279= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV65032281, COSV65035080; called by muse, mutect2, varscan2
- ZSCAN1 | c.996C>T p.N332= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV56602539, COSV56608435; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849352 G>T | 5'Flank (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ANKHD1 | c.1782+7534T>G | Intron (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99782108; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499025 C>T | 5'Flank (SNP) | VAF 37/137 reads (27%) | catalogued as rs754994464; called by muse, mutect2, varscan2
- CGAS | c.-2C>G | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100943620; called by muse, mutect2, varscan2
- DCHS2 | n.8276G>A | RNA (SNP) | VAF 22/53 reads (42%) | catalogued as rs771804142, COSV61769108; called by muse, mutect2, varscan2
- HERC2P3 | n.734C>A | RNA (SNP) | VAF 25/254 reads (10%) | called by muse, mutect2
- ZNF271P | n.1259G>C | RNA (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
